Gene-level copy-number profile of tumor specimen ALCH-B2SY-TTP1-A from ALCHEMIST case ALCH-B2SY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.9 years (24,797 days).
Specimen ALCH-B2SY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 037ad4d9-bf5a-40e4-9d68-09e03e94ec31.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/fd1628a8-f085-46d8-988b-af7330f895b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,108; copy number 2: 50,598; copy number 3: 6,606; copy number 4: 47; copy number 5: 2; copy number 9: 1; copy number 11: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,492,300–2,526,597, 3 genes (within-gene range 0–1): AL139246.1, AL139246.4, PANK4.
- chr7:158,532,718–158,539,879, 2 genes (within-gene range 0–1): MIR595, AC078942.1.
- chr9:136,647,872–136,672,678, 3 genes: AL590226.1, EGFL7, MIR126.
- chr11:45,647,689–45,665,622, 2 genes: CHST1, AC087442.1.
- chr11:62,787,402–62,790,400, 2 genes (within-gene range 0–3): TMEM179B, MIR6748.
- chr11:65,787,063–65,797,219, 3 genes (within-gene range 0–2): OVOL1, OVOL1-AS1, AP001266.1.
- chr14:105,486,317–105,499,575, 3 genes: CRIP1, AL928654.3, TEDC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:50,705,380–50,708,906, 1 gene, copy number 5: CTSLP4.
- chr15:20,835,372–20,866,314, 2 genes, copy number 11: POTEB2, RNU6-749P.
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 9–13: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 1,107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
